Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A87Q, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A87Q-01A (Primary Tumor).

[page 1 of 7]
Clinical History: Craniotomy Tumor
Pre-Operative Diagnoses: None Given
Post-Operative Diagnosis: Same
Specimen(s) Submitted: A. Brain Tumor; B. Brain Tumor; C. Brain Tumor
CPT Code(s): 88307 X 3; 88333 X 1; 88342 X 2; 88360 X 1

FINAL DIAGNOSIS:

- A. Brain tumor: Anaplastic astrocytoma, WHO grade 3. See note.
- B. Brain tumor: Anaplastic astrocytoma, WHO grade 3. See note.
- C. Brain tumor: Anaplastic astrocytoma, WHO grade 3. See note.

Note: The tumor consists of neoplastic astrocytes, with "naked" infiltrating nuclei. Patchy, marked nuclear pleomorphism with bizarre nuclei as well as hypercellularity are seen. Tumor infiltrates cortex, with perineuronal satellitosis. Mitoses are identified, but no necrosis or vascular endothelial proliferation are present. Immunostain for p53 is focally positive, IDH is negative. Immunostain for Ki67 is diffusely increased, to 23%. The tumor corresponds to a WHO grade 3. MGMT and 1p 19q have been sent.

BRAIN: Resection

MACROSCOPIC

Specimen Type

☒ Resection

Tumor Site

☒ Cerebrum

ICD O-3
Astrocytoma, grade III 9401/3
Site ~~PLCE~~ Brain, supratentorial NOS
path C71.0
Cerebrum C71.0
JW 11/12/13

Technical Performing Location:

questions regarding this case:

For

[page 2 of 7]
Tumor Size

X Cannot be determined

MICROSCOPIC

Histologic Type

X Anaplastic astrocytoma

Histologic Grade

X WHO Grade 3

Frozen Section Diagnosis:

A. Brain tumor (SMA):

- Infiltrating astrocytoma.

██████████ (16 minutes) ██████████

Gross Description:

A. Received fresh for frozen section diagnosis, labeled with the patient's name, ██████████ and "brain tumor", is a 0.6 g, 1.5 x 1.2 x 0.2 cm aggregate of multiple irregular tan soft tissue fragments which are entirely submitted in cassette ██████████ A1 and A2.

B. Received fresh, labeled with the patient's name ██████████ and "brain tumor," is a 0.6 g, 1.4 x 1.2 x 0.2 cm aggregate of irregular tan to tan-pink soft tissue fragments. A portion of the specimen is taken for tissue bank and the remaining specimen is entirely submitted in cassette ██████████ B1 and B2.

C. Received fresh and labeled with the patient's name ██████████ and "brain tumor," is a 2 g, 3 x 1.5 x 0.6 cm aggregate of irregular tan-pink-white soft tissue fragments. A portion of specimen is taken for tissue bank and the remaining specimen is sectioned and entirely submitted in cassettes ██████████ C1-C4.

Microscopic Description:

8 H&E. Immunostains for p53 and IDH; Ki67, semiquant.

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

[page 3 of 7]
The pathologist signing this report is located at

[REDACTED]

[REDACTED]

[REDACTED]
Pathologist

Electronically signed [REDACTED]

[page 4 of 7]
Patient Name: [REDACTED]
Ordering Physician: [REDACTED]
Treating Physician: [REDACTED]
Ordering Facility: [REDACTED]
Medical Record #: [REDACTED]
Date of Birth, Sex: [REDACTED]

Collection Date: [REDACTED]
Received Date: [REDACTED]
Report Date: [REDACTED]
Specimen ID #: [REDACTED]

Fluorescence in situ Hybridization Analysis Report

FISH

FISH Paraffin Block Test

Specimen Type

Paraffin block

Cells Counted

100

Cells Analyzed

100

FISH Result

NEGATIVE FOR 1P/19Q CO-DELETION

POSITIVE FOR A RELATIVE DELETION OF 19Q

Interpretation

RELATIVE DELETION OF 19q nuc ish 1p36(TP73)x2, 1q25(ANGPTL)x2[100] 19q13(GLTSCR)x2, 19p13(ZNF443)x3[52/100]

The fluorescence in situ hybridization (FISH), using a distal 1p short arm DNA probe and a distal 19q DNA probe, and control sequences at 1q25 and 19p13 was negative for a 1p/19q deletion. FISH did reveal additional a loss of 19q in a polysomy background. Loss of 19q is shared by all three glioma subtypes with deletions occurring in 40% of astrocytomas, 45% of mixed oligoastrocytomas and 75% of oligodendrogliomas. All paraffin-embedded tissues referred for FISH testing are reviewed by a pathologist at the location.

Block ID: [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

[page 5 of 7]
Disclaimer

This Test was performed at [REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

This document contains private and confidential health information protected by state and federal law. If you received this document in error, please call [REDACTED]

[page 6 of 7]
Reference

1. Vliessenbroeck J. et al. Validation of Real-Time Methylation-Specific PCR to Determine O(6)-Methylguanine-DNA Methyltransferase Gene Promoter Methylation in Glioma. J. Molecular Diagnostics 10; 4:332-337. 2008.
2. Hegi M. et al. MGMT Gene Silencing and Benefit from Temozolomide in Glioblastoma. New England J Medicine 352; 10:997-1003. 2005.
3. Brandes A. et al. MGMT Promoter Methylation Status Correlates with Response to Temozolomide in Glioblastoma After Concurrent

Molecular Analysis Report

Test Performed

MGMT Methylation Assay

Specimen Type

Paraffin block

Result

Gene Methylation DETECTED

Methylation of the MGMT (O(6)-methylguanine-DNA methyltransferase) gene was detected using methylation specific PCR technologies.

Methylation Score: 20.11
unmethylated <2.00
methylated >=2.00

Background

MGMT (O(6)-methylguanine-DNA methyltransferase) is a DNA repair enzyme that is involved in the repair of damage caused by a variety of DNA crosslinking compounds, including alkylating agents. Increased methylation of the MGMT gene promoter region causes diminished or silenced expression of the gene, making cells more sensitive to DNA damage. This relationship has been shown for glioblastomas and alkylating agents such as Temodar(R)(temozolomide). Approximately 40% to 45% of glioblastoma multiforme (GBM) tumors exhibit MGMT gene methylation. Retrospective studies have shown that detection of MGMT promoter methylation in tumor samples is associated with an increased likelihood of a favorable response to temozolomide.

Methodology

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimen. Molecular analysis of the MGMT gene is performed by methylation-specific PCR and detected on ABI7900. The MGMT and beta-Actin copy numbers will be used to calculate the ratio of MGMT/beta-Actin x1000. Molecular-based testing is highly accurate, but as in any laboratory test, rare diagnostic errors may occur. Results of this test are for Investigational Purposes Only. The performance characteristic of this assay have been determined by the result should not be used as a diagnostic procedure without confirmation of the diagnosis by another medically established diagnostic product or procedure.

Comments

Block ID [REDACTED]

[page 7 of 7]
Reference

1. Vlassenbroeck I. et al. Validation of Real-Time Methylation-Specific PCR to Determine O(6)-Methylguanine-DNA Methyltransferase Gene Promoter Methylation in Glioma. *J. Molecular Diagnostics* 10; 4:332-337. 2008.
2. Hegi M. et al. MGMT Gene Silencing and Benefit from Temozolomide in Glioblastoma. *New England J Medicine* 352; 10:997-1003. 2005.
3. Brandes A. et al. MGMT Promoter Methylation Status Can Predict the Incidence and Outcome of Pseudoprogression After Concomitant Radiochemotherapy in Newly Diagnosed Glioblastoma Patients. *J. Clinical Oncology* 26; 13:2192-2197. 2008.
4. Hau P. et al. MGMT Methylation Status: The Advent of Stratified Therapy in Glioblastoma. *Disease Markers* 23:97-104. 2007.

Disclaimer

This Test was performed at [REDACTED]

This document contains private and confidential health information protected by state and federal law. If you received this document in error, please call [REDACTED]

Pathologist [REDACTED]

Electronically signed [REDACTED]

Source: NCI Genomic Data Commons file dc207ff9-6664-41f6-a694-d64f2336d3e5 (TCGA-FG-A87Q.072A2905-3E7F-4C11-87A2-3D4577F1F8A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).